Somatic mutation profile of tumor specimen TCGA-12-5301-01A (aliquot TCGA-12-5301-01A-01D-1486-08) from TCGA case TCGA-12-5301, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.6 years (21,768 days).
Specimen TCGA-12-5301-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64122701-eac5-4dba-90fb-921512a3f99a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-5301-10A (Blood Derived Normal), aliquot TCGA-12-5301-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93cc0e41-08c7-4bd9-a910-3fafb9deadf8

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 40, Silent 19, Nonsense Mutation 4, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F9 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 123/142 reads (87%) | catalogued as rs137852250, CM940596, COSV54379173; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRT6B | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs60627726, CM981147, COSV52882395; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 99/227 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 64/160 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, varscan2
- AC104452.1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as COSV55533909; called by muse, mutect2, varscan2
- ANPEP | c.867C>G p.Y289* | Nonsense Mutation (SNP) | VAF 139/293 reads (47%) | catalogued as COSV100262702, COSV55589822; called by muse, mutect2, varscan2
- CACNA1D | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV55440195; called by muse, mutect2, varscan2
- CALCR | c.796G>A p.V266M (on ENST00000649521 / NM_001164737.2; = p.V250M on NM_001742.4) | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs548671354, COSV64006450; called by muse, mutect2, varscan2
- CDH22 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.589); catalogued as COSV64836738; called by muse, mutect2, varscan2
- CEP76 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs754183790, COSV50865624; called by muse, mutect2, varscan2
- DBH | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372946596; called by muse, mutect2, varscan2
- DNAH2 | c.4865G>A p.R1622Q | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs201053374, COSV66717371; called by muse, mutect2, varscan2
- EPHB6 | c.2987T>A p.L996Q | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63890873; called by muse, mutect2, varscan2
- FGD4 | c.1134A>G p.K378= | Splice Region (SNP) | VAF 43/113 reads (38%) | catalogued as COSV56781151; called by muse, mutect2, varscan2
- FOXB2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as COSV65022521; called by muse, mutect2, varscan2
- GABRB2 | c.1351T>C p.F451L (on ENST00000274547; = p.F413L on NM_000813.3) | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV50904457; called by muse, mutect2, varscan2
- GCSAM | c.99A>G p.R33= | Splice Region (SNP) | VAF 4/98 reads (4%) | catalogued as COSV58262834; called by muse, mutect2
- GPR179 | c.4468G>A p.G1490R (on ENST00000621958; = p.G1489R on NM_001004334.4) | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as rs1397301341; called by muse, mutect2, varscan2
- HEY2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV64239484; called by muse, mutect2, varscan2
- JPH2 | c.869C>G p.T290S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV65902225, COSV65904049; called by muse, mutect2, varscan2
- KDM7A | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs550261955, COSV50090317; called by muse, mutect2, varscan2
- KDR | c.2881C>T p.R961W | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs530419081, COSV55759748; called by muse, mutect2, varscan2
- KHDC3L | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV64863028; called by muse, mutect2, varscan2
- KRT75 | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs201563619, COSV52871385; called by muse, mutect2, varscan2
- MUC4 | c.14996C>T p.T4999M (on ENST00000463781 / NM_018406.7; = p.T763M on NM_004532.6) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); catalogued as rs367749099; called by muse, mutect2, varscan2
- MYO15A | c.6256G>A p.V2086M | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs369781492; called by muse, mutect2, varscan2
- NALCN | c.5120C>T p.T1707I | Missense Mutation (SNP) | VAF 148/361 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV51922501; called by muse, mutect2, varscan2
- NBEA | c.6624G>A p.M2208I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV59765821; called by muse, mutect2, varscan2
- NPY4R | c.25T>A p.L9M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.087); catalogued as COSV65397681; called by mutect2, varscan2
- NUP210L | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 57/150 reads (38%) | catalogued as rs771522844, COSV55141015; called by muse, varscan2
- OR1A1 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs144175148; called by muse, mutect2, varscan2
- OR5I1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs565054095, COSV56885782; called by muse, mutect2, varscan2
- OR5P2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 128/305 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs765255136, COSV61490080; called by muse, mutect2, varscan2
- PARP4 | c.1484A>G p.D495G | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1432380874, COSV67960876; called by muse, mutect2, varscan2
- SLC6A18 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.077); catalogued as rs138941918; called by muse, mutect2, varscan2
- SLITRK1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65674582, COSV65675692; called by muse, mutect2, varscan2
- THADA | c.3166A>C p.S1056R | Missense Mutation (SNP) | VAF 179/435 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57677917; called by muse, mutect2, varscan2
- TUBGCP6 | c.4534C>T p.H1512Y | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV50538296; called by muse, mutect2, varscan2
- USP16 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199586396; called by muse, mutect2, varscan2
- VIL1 | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV50285800; called by muse, mutect2, varscan2
- WNT8A | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs779974983, COSV64230869; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1311A>C p.K437N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56271980; called by muse, mutect2, varscan2
- ZNF215 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 59/164 reads (36%) | catalogued as rs368370827; called by muse, mutect2, varscan2
- ZNF451 | c.2281A>G p.T761A | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1562623156, COSV62596875; called by muse, mutect2, varscan2
- ZNF618 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 147/351 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs143368881; called by muse, mutect2, varscan2
- ZSWIM8 | c.2636C>G p.A879G | Missense Mutation (SNP) | VAF 85/118 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV67131407, COSV67134301; called by muse, mutect2, varscan2
- FBLN1 | c.1473_1476dup p.I493Pfs*36 | Frame Shift Ins (INS) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- ANO4 | c.21A>G p.G7= | Silent (SNP) | VAF 97/216 reads (45%) | catalogued as COSV54588296; called by muse, mutect2, varscan2
- ATP8B1 | c.2640G>A p.V880= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV52173547; called by muse, mutect2, varscan2
- CCIN | c.1362C>T p.D454= | Silent (SNP) | VAF 96/219 reads (44%) | catalogued as rs562247970, COSV58724192; called by muse, mutect2, varscan2
- CTSG | c.108G>A p.A36= | Silent (SNP) | VAF 143/360 reads (40%) | catalogued as rs377162733, COSV53534848; called by muse, mutect2, varscan2
- FBN2 | c.6834G>A p.T2278= | Silent (SNP) | VAF 97/241 reads (40%) | catalogued as rs374853253; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGD5 | c.849G>A p.T283= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as rs774201861, COSV53238806; called by muse, mutect2, varscan2
- GAA | c.1308G>T p.R436= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV56407336; called by muse, mutect2, varscan2
- KMT2B | c.4764G>A p.G1588= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as rs1305687241, COSV55858261; called by muse, mutect2, varscan2
- MC5R | c.603G>T p.L201= | Silent (SNP) | VAF 399/1018 reads (39%) | catalogued as COSV61254079, COSV61255399; called by muse, mutect2, varscan2
- NLRP12 | c.789C>T p.S263= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV60744384; called by muse, mutect2, varscan2
- OR2T11 | c.133T>C p.L45= | Silent (SNP) | VAF 65/167 reads (39%) | catalogued as COSV58184966; called by muse, mutect2, varscan2
- PROSER2 | c.258G>A p.V86= | Silent (SNP) | VAF 41/58 reads (71%) | catalogued as COSV53204674; called by muse, mutect2, varscan2
- RBBP6 | c.162A>G p.K54= | Silent (SNP) | VAF 52/72 reads (72%) | catalogued as COSV60503773; called by muse, mutect2, varscan2
- SLC49A3 | c.309G>A p.A103= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs371460109, COSV59141885; called by muse, mutect2, varscan2
- SPRR1B | c.33C>G p.T11= | Silent (SNP) | VAF 94/336 reads (28%) | catalogued as COSV61067479; called by muse, mutect2
- SUPT16H | c.2328G>A p.L776= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV53522834; called by muse, mutect2, varscan2
- TMEM215 | c.636C>T p.N212= | Silent (SNP) | VAF 93/251 reads (37%) | catalogued as COSV61363228; called by muse, mutect2, varscan2
- TPSD1 | c.174C>T p.R58= | Silent (SNP) | VAF 68/181 reads (38%) | catalogued as rs778229260, COSV52974243; called by muse, varscan2
- TRANK1 | c.6540G>A p.S2180= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as rs867659681, COSV57143588; called by muse, mutect2, varscan2
